Somatic mutation profile of tumor specimen C3N-02333-02 (aliquot CPT0176770006) from CPTAC case C3N-02333, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 61.0 years (22,285 days).
Specimen C3N-02333-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dd6d4629-8366-4c90-9a51-03b47626d082.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02333-71 (Blood Derived Normal), aliquot CPT0176950002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/406fba9a-c0f2-49ff-b195-baf033edec2f

The open-access MAF lists 405 somatic variants for this specimen: 273 protein-altering or splice-affecting, 90 silent, 42 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 244, Silent 90, Intron 21, Nonsense Mutation 13, 3'UTR 7, RNA 5, Splice Region 5, Frame Shift Del 4, 5'UTR 4, Frame Shift Ins 4, 3'Flank 3, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTOR | c.6644C>T p.S2215F | Missense Mutation (SNP) | VAF 15/106 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs587777894, COSV63868278, COSV63868313; ClinVar: not provided / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.799C>T p.R267W | Missense Mutation (SNP) | VAF 66/477 reads (14%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.835); catalogued as rs55832599, CM120851, COSV52678166, COSV52736883, COSV52827473; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA3 | c.349G>C p.E117Q | Missense Mutation (SNP) | VAF 27/338 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV100068625; called by muse, mutect2
- AC073610.2 | c.440C>G p.S147C | Missense Mutation (SNP) | VAF 33/238 reads (14%) | SIFT deleterious, low confidence (0.03); catalogued as COSV57197661; called by muse, mutect2, varscan2
- ACTR5 | c.1815G>C p.E605D | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as rs145297164; called by muse, varscan2
- ADGB | c.4477G>A p.G1493R | Missense Mutation (SNP) | VAF 44/337 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.121); catalogued as COSV58848022; called by muse, mutect2, varscan2
- ADSS2 | c.613A>G p.I205V | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1372617460, COSV63695744; called by muse, mutect2
- AGT | c.941C>G p.S314C | Missense Mutation (SNP) | VAF 15/264 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1478226147, COSV64184500; called by muse, mutect2
- ANKFN1 | c.3280G>A p.D1094N (on ENST00000653862; = p.D947N on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/368 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs758031860; called by muse, mutect2
- AP3B2 | c.1729G>T p.D577Y | Missense Mutation (SNP) | VAF 28/262 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55607487; called by muse, mutect2, varscan2
- ASIC1 | c.1403G>A p.R468Q | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as rs770761778; called by muse, mutect2
- BAZ1B | c.1567C>T p.Q523* | Nonsense Mutation (SNP) | VAF 29/167 reads (17%) | catalogued as COSV59990456; called by muse, mutect2, varscan2
- BHLHE22 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 15/220 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as rs1296848862, COSV58861327, COSV58863066; called by muse, mutect2
- BICD1 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99861857; called by muse, mutect2, varscan2
- BIN3 | c.61G>C p.E21Q | Missense Mutation (SNP) | VAF 13/184 reads (7%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.95); catalogued as COSV99374292; called by muse, mutect2
- CARD11 | c.1500G>A p.M500I | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs1286226733; called by muse, varscan2
- CDC14B | c.821C>T p.T274M | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs753779684; called by muse, mutect2, varscan2
- CDK11A | c.2009A>G p.N670S (on ENST00000378633 / NM_001313896.2; = p.N667S on NM_024011.4) | Missense Mutation (SNP) | VAF 29/342 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as rs986085109; called by muse, mutect2
- CDYL2 | c.1243C>T p.R415W | Missense Mutation (SNP) | VAF 26/221 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as rs1273478313, COSV73653976; called by muse, mutect2, varscan2
- CHEK2 | c.815G>A p.G272D (on ENST00000382580 / NM_001005735.2; = p.G229D on NM_007194.4) | Missense Mutation (SNP) | VAF 55/232 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778212685; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHRNB3 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs1316872227, COSV51493201; called by muse, mutect2
- CPNE5 | c.1697G>A p.R566H | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.208); catalogued as rs747767268, COSV55195387; called by muse, mutect2
- DCDC2 | c.1130G>T p.G377V | Missense Mutation (SNP) | VAF 26/273 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV65828485; called by muse, mutect2
- DCST1 | c.647G>A p.G216E | Missense Mutation (SNP) | VAF 76/406 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1160179576; called by muse, mutect2, varscan2
- DEUP1 | c.751C>T p.L251F | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.584); catalogued as COSV99977586; called by muse, mutect2
- DHODH | c.893C>T p.S298F | Missense Mutation (SNP) | VAF 57/490 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); catalogued as COSV54661290; called by muse, mutect2, varscan2
- DIO3 | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 40/442 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1278981254; called by muse, mutect2
- DNAI1 | c.1887G>C p.K629N | Missense Mutation (SNP) | VAF 39/336 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV54279937; called by muse, mutect2, varscan2
- DSP | c.4267C>T p.L1423F | Missense Mutation (SNP) | VAF 12/228 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.942); catalogued as rs866653266; called by muse, mutect2
- EGR3 | c.825C>A p.H275Q | Missense Mutation (SNP) | VAF 37/212 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100416131; called by muse, mutect2, varscan2
- EME2 | c.356G>C p.R119P | Missense Mutation (SNP) | VAF 11/233 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.221); catalogued as rs1271652829; called by muse, mutect2
- ENTHD1 | c.824C>G p.S275W | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57317661; called by muse, mutect2
- FAM161B | c.317G>A p.R106K (on ENST00000651776; = p.R43K on NM_152445.3) | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.329); catalogued as COSV53179414; called by muse, mutect2
- FBXO22 | c.277G>C p.E93Q | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.17); catalogued as rs1488817434; called by muse, mutect2
- FCRL5 | c.2753G>A p.R918K | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as COSV62513196; called by muse, mutect2
- FGF9 | c.166C>T p.H56Y | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV66645737; called by muse, mutect2
- FIGLA | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs1558600580; called by muse, mutect2, varscan2
- FLG | c.8715G>C p.E2905D | Missense Mutation (SNP) | VAF 26/1080 reads (2%) | SIFT tolerated (0.43); PolyPhen benign (0.011); catalogued as COSV64246751; called by muse, mutect2
- FRY | c.8674G>A p.A2892T | Missense Mutation (SNP) | VAF 39/373 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.029); catalogued as rs540098914, COSV66510786; called by muse, mutect2, varscan2
- GET4 | c.653C>T p.T218M | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as rs1484935592; called by muse, mutect2
- GFRA1 | c.953G>T p.S318I | Missense Mutation (SNP) | VAF 26/265 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100815469; called by muse, mutect2, varscan2
- GOLGA6A | c.1426-5C>G | Splice Region (SNP) | VAF 56/1057 reads (5%) | catalogued as rs1195188973; called by muse, mutect2
- GRM8 | c.1940T>C p.I647T | Missense Mutation (SNP) | VAF 42/199 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as rs138004157; called by muse, mutect2, varscan2
- HECTD1 | c.2993G>A p.R998K | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.13); catalogued as rs961869282; called by muse, mutect2
- HEPHL1 | c.2038C>T p.P680S | Missense Mutation (SNP) | VAF 28/322 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1294132431; called by muse, mutect2
- HPS1 | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV100282393; called by muse, mutect2, varscan2
- HTRA4 | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 13/169 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); catalogued as COSV56760669; called by muse, mutect2
- IRF6 | c.723G>T p.M241I | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV65419203; called by muse, mutect2, varscan2
- IRS2 | c.3143C>T p.S1048L | Missense Mutation (SNP) | VAF 22/352 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV65477353; called by muse, mutect2
- JMJD8 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 23/217 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.137); catalogued as rs778481377, COSV50197729; called by muse, mutect2, varscan2
- KCTD16 | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 31/266 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as rs867663751, COSV101568935; called by muse, mutect2, varscan2
- KIAA1210 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs747393355, COSV68177862; called by muse, mutect2, varscan2
- LLPH | c.259C>G p.L87V | Missense Mutation (SNP) | VAF 15/168 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs1428966455; called by muse, mutect2
- MAP3K8 | c.1297G>A p.E433K | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs145710720; called by muse, mutect2, varscan2
- MGMT | c.497G>C p.R166T (on ENST00000306010; = p.R135T on NM_002412.5) | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV100022824; called by muse, mutect2, varscan2
- MICALL2 | c.130C>T p.R44W | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866917760; called by muse, mutect2
- MRPL39 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs1260583554; called by muse, varscan2
- MYC | c.772G>T p.D258Y (on ENST00000377970; = p.D273Y on NM_002467.6) | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV52370057; called by muse, mutect2, varscan2
- NACAD | c.1844C>T p.S615L | Missense Mutation (SNP) | VAF 27/216 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV71989459; called by muse, varscan2
- NCCRP1 | c.620C>A p.T207K | Missense Mutation (SNP) | VAF 23/230 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); catalogued as COSV59212772; called by muse, mutect2, varscan2
- NLGN2 | c.346G>T p.A116S | Missense Mutation (SNP) | VAF 82/543 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.1); catalogued as rs942694026; called by muse, mutect2, varscan2
- NME1 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 13/185 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.668); catalogued as rs776130833; called by muse, mutect2
- NMU | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as COSV99946668; called by muse, mutect2, varscan2
- NTAN1 | c.703T>C p.F235L | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs778891642; called by muse, mutect2
- NTNG1 | c.116C>T p.T39M | Missense Mutation (SNP) | VAF 25/233 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); catalogued as rs776588522, COSV104398510; called by muse, mutect2, varscan2
- OR10X1 | c.856C>G p.L286V | Missense Mutation (SNP) | VAF 24/248 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as rs1490780659, COSV63767716, COSV63767989; called by muse, mutect2
- OR2H2 | c.674G>C p.R225T | Missense Mutation (SNP) | VAF 32/290 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.088); catalogued as COSV63542486; called by muse, mutect2, varscan2
- OR4K17 | c.906G>A p.W302* | Nonsense Mutation (SNP) | VAF 4/30 reads (13%) | catalogued as COSV100210695; called by muse, mutect2
- OR51G2 | c.391A>G p.I131V | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as COSV58992464; called by muse, mutect2, varscan2
- OTOA | c.1441C>T p.R481C (on ENST00000286149; = p.R467C on NM_144672.4) | Missense Mutation (SNP) | VAF 57/473 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.613); catalogued as rs757720270, COSV53750032; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PADI2 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 16/213 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs140400053, COSV100970939; called by muse, mutect2
- PASK | c.2479G>C p.E827Q | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.014); catalogued as COSV52156450; called by muse, mutect2, varscan2
- PCDH1 | c.676G>C p.E226Q | Missense Mutation (SNP) | VAF 27/404 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as rs1488066254; called by muse, mutect2
- PCDHA8 | c.287G>A p.C96Y | Missense Mutation (SNP) | VAF 57/662 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs555005640; called by muse, mutect2
- PCDHB5 | c.1610C>A p.S537Y | Missense Mutation (SNP) | VAF 85/858 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.33); catalogued as COSV99167566; called by muse, mutect2
- PCED1B | c.363G>T p.M121I | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.066); catalogued as COSV71395414; called by muse, mutect2, varscan2
- PCNT | c.2524G>A p.E842K | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.775); catalogued as rs1291503523, COSV64025049, COSV64025882, COSV64029451; called by muse, mutect2
- PDCD7 | c.748C>A p.R250S | Missense Mutation (SNP) | VAF 58/668 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.7); catalogued as COSV99200141; called by muse, mutect2
- PIEZO2 | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 31/309 reads (10%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.958); catalogued as rs1310236262, COSV100123976; called by muse, mutect2, varscan2
- PPT2 | c.742G>A p.V248I | Missense Mutation (SNP) | VAF 24/248 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.125); catalogued as rs941565441; called by muse, mutect2
- PSMD7 | c.152C>T p.S51L | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as rs1422076663, COSV54697768; called by muse, mutect2
- RAI1 | c.1681C>T p.P561S | Missense Mutation (SNP) | VAF 46/506 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs748884239; called by muse, mutect2
- RP1L1 | c.5515G>A p.E1839K | Missense Mutation (SNP) | VAF 35/287 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs777623753, COSV66752131; called by muse, mutect2, varscan2
- RXFP4 | c.491C>A p.A164E | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.281); catalogued as rs755905775; called by muse, mutect2
- SEZ6L2 | c.1207C>A p.R403= (on ENST00000308713 / NM_001114099.3; = p.R333= on NM_012410.4) | Splice Region (SNP) | VAF 6/64 reads (9%) | catalogued as COSV58103041; called by muse, mutect2
- SGK3 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs755143437; called by muse, mutect2, varscan2
- SLC26A3 | c.2006C>A p.S669* | Nonsense Mutation (SNP) | VAF 34/215 reads (16%) | catalogued as rs762034228, COSV60639201; called by muse, mutect2, varscan2
- SLC29A4 | c.28G>C p.E10Q | Missense Mutation (SNP) | VAF 29/458 reads (6%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as COSV51874236; called by muse, mutect2
- SLC5A5 | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 65/565 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); catalogued as rs780149458; called by muse, mutect2, varscan2
- SNX1 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs763649714; called by muse, mutect2, varscan2
- SPHKAP | c.4954G>C p.E1652Q (on ENST00000392056 / NM_001142644.2; = p.E1623Q on NM_030623.3) | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.966); catalogued as COSV60875548, COSV60886813; called by muse, mutect2
- SPIC | c.560G>A p.R187K | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV100162851; called by muse, mutect2, varscan2
- ST8SIA5 | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 20/339 reads (6%) | PolyPhen probably damaging (0.995); catalogued as COSV59333510; called by muse, mutect2
- TCTN3 | c.911C>A p.T304N | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.062); catalogued as rs1024201294; called by muse, mutect2, varscan2
- TDRD6 | c.4877C>T p.S1626L | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs137987343; called by muse, mutect2, varscan2
- TIMP2 | c.582C>G p.I194M | Missense Mutation (SNP) | VAF 28/428 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.916); catalogued as COSV53159585; called by muse, mutect2
- TNPO2 | c.473C>G p.S158* | Nonsense Mutation (SNP) | VAF 21/214 reads (10%) | catalogued as COSV63509083; called by muse, mutect2
- TRAF4 | c.1179G>C p.Q393H | Missense Mutation (SNP) | VAF 31/372 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs767917830; called by muse, mutect2
- TTN | c.87355G>C p.E29119Q (on ENST00000591111; = p.E21695Q on NM_003319.4) | Missense Mutation (SNP) | VAF 16/156 reads (10%) | PolyPhen possibly damaging (0.776); catalogued as rs936029222, COSV59881575; called by muse, mutect2
- UNC45A | c.2231A>G p.N744S | Missense Mutation (SNP) | VAF 27/314 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs747476342; called by muse, mutect2
- UNC5C | c.1022C>T p.T341M | Missense Mutation (SNP) | VAF 16/171 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.594); catalogued as rs775796452, COSV71661666; called by muse, mutect2
- VWF | c.5473A>G p.I1825V | Missense Mutation (SNP) | VAF 26/322 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.044); catalogued as rs372430819; called by muse, mutect2
- WDFY4 | c.585C>G p.F195L | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs573178287, COSV57432793; called by muse, mutect2, varscan2
- ZC3H7B | c.2500G>A p.D834N | Missense Mutation (SNP) | VAF 9/180 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60962491; called by muse, mutect2
- ZER1 | c.1951G>A p.V651I | Missense Mutation (SNP) | VAF 18/241 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201752916, COSV52567674; called by muse, mutect2
- ZNF135 | c.1158G>C p.E386D (on ENST00000313434 / NM_001289401.2; = p.E398D on NM_003436.4) | Missense Mutation (SNP) | VAF 26/259 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.295); catalogued as rs542980013; called by muse, mutect2, varscan2
- ZNF70 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 34/302 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.27); catalogued as rs768697096; called by muse, mutect2, varscan2
- ZNF700 | c.977G>T p.R326M | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as COSV54315374; called by muse, mutect2
- ABCG2 | c.351C>G p.F117L | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); called by muse, mutect2
- ACBD5 | c.224A>G p.Y75C (on ENST00000375888 / NM_001352568.1; = p.Y77C on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/201 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACVRL1 | c.730G>C p.E244Q | Missense Mutation (SNP) | VAF 27/278 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); called by muse, mutect2
- ADAMTS17 | c.2205G>C p.Q735H | Missense Mutation (SNP) | VAF 43/514 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.942); called by muse, mutect2
- ANKRD17 | c.5093T>G p.L1698R | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.758); called by muse, mutect2
- ANTXR2 | c.1443del p.E481Dfs*7 | Frame Shift Del (DEL) | VAF 15/134 reads (11%) | called by mutect2, pindel, varscan2
- APBA2 | c.1933A>T p.T645S | Missense Mutation (SNP) | VAF 56/475 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ARHGEF17 | c.2092G>C p.E698Q | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.31); called by muse, mutect2
- ATAD2 | c.2495G>T p.G832V | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- ATAD3A | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 62/534 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- AWAT1 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BIRC6 | c.9886A>G p.I3296V | Missense Mutation (SNP) | VAF 16/239 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.755); called by muse, mutect2
- BUB1B | c.449C>A p.S150* | Nonsense Mutation (SNP) | VAF 20/174 reads (11%) | called by muse, mutect2, varscan2
- C4B | c.3314A>T p.N1105I | Missense Mutation (SNP) | VAF 80/739 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- C7 | c.1169A>G p.Y390C | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- CACNA1G | c.6940G>C p.D2314H | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.429); called by muse, mutect2, varscan2
- CADM2 | c.505G>T p.V169L (on ENST00000407528 / NM_001167674.2; = p.V171L on NM_153184.4) | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, varscan2
- CASKIN2 | c.642G>C p.E214D | Missense Mutation (SNP) | VAF 16/292 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.08); called by muse, mutect2
- CASP7 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 8/228 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- CCDC168 | c.11765G>C p.R3922T | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- CD2AP | c.605C>G p.S202C | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.155); called by muse, mutect2
- CDKL5 | c.841G>T p.D281Y | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- CEACAM5 | c.1788dup p.I597Hfs*24 | Frame Shift Ins (INS) | VAF 9/98 reads (9%) | called by mutect2, pindel
- COL22A1 | c.56G>A p.W19* | Nonsense Mutation (SNP) | VAF 22/370 reads (6%) | called by muse, mutect2
- CPB2 | c.598C>G p.Q200E | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CROCC2 | c.3604A>T p.K1202* | Nonsense Mutation (SNP) | VAF 22/176 reads (13%) | called by muse, mutect2, varscan2
- CSMD1 | c.521G>T p.G174V | Missense Mutation (SNP) | VAF 25/263 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CSMD2 | c.7253C>G p.S2418* | Nonsense Mutation (SNP) | VAF 7/77 reads (9%) | called by muse, mutect2
- CYLC1 | c.1829C>T p.P610L | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); called by muse, mutect2
- DIAPH3 | c.1896dup p.G633Wfs*9 (on ENST00000400324 / NM_001042517.2; = p.G370Wfs*9 on NM_030932.3) | Frame Shift Ins (INS) | VAF 12/128 reads (9%) | called by mutect2, pindel
- DMTN | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 40/376 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); called by muse, mutect2
- DNAH11 | c.4442C>A p.T1481K | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- DSP | c.5587G>C p.D1863H | Missense Mutation (SNP) | VAF 10/177 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2
- EIF2AK2 | c.811G>C p.E271Q | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.312); called by muse, mutect2
- EIF4A1 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 12/222 reads (5%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.07); called by muse, mutect2
- ESRRA | c.312G>C p.K104N | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- EYS | c.1185C>T p.S395= | Splice Region (SNP) | VAF 7/108 reads (6%) | called by muse, mutect2
- F13A1 | c.140A>C p.N47T | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2
- FADS3 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0.037); called by muse, mutect2
- FAM155A | c.332G>C p.G111A | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.434); called by muse, varscan2
- FAM181B | c.211G>T p.D71Y | Missense Mutation (SNP) | VAF 55/536 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- FANCG | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 38/558 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2
- FAT1 | c.1666del p.T556Qfs*7 | Frame Shift Del (DEL) | VAF 17/152 reads (11%) | called by mutect2, varscan2
- FIGN | c.1308G>T p.Q436H | Missense Mutation (SNP) | VAF 27/328 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.005); called by muse, mutect2
- FKBP3 | c.359A>T p.D120V | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.096); called by muse, mutect2
- FOSL2 | c.578_599del p.I193Sfs*20 | Frame Shift Del (DEL) | VAF 26/258 reads (10%) | called by mutect2, pindel
- FREM1 | c.6325A>G p.K2109E | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- FSIP2 | c.2939C>T p.S980L | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- GANC | c.1096C>T p.H366Y | Missense Mutation (SNP) | VAF 17/215 reads (8%) | PolyPhen probably damaging (1); called by muse, mutect2
- GBX1 | c.541G>C p.E181Q | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.867); called by muse, mutect2
- GMPS | c.818G>A p.G273D | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GPR143 | c.763A>G p.I255V | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- GPR157 | c.181G>T p.A61S | Missense Mutation (SNP) | VAF 34/240 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- GPT2 | c.1165G>T p.V389L | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- GRID2IP | c.2130G>A p.M710I | Missense Mutation (SNP) | VAF 21/262 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.262); called by muse, mutect2
- GRIK3 | c.374G>T p.C125F | Missense Mutation (SNP) | VAF 34/362 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2
- GSDMC | c.944-1G>C p.X315_splice | Splice Site (SNP) | VAF 9/72 reads (13%) | called by muse, mutect2
- GTF3C1 | c.2423G>A p.W808* | Nonsense Mutation (SNP) | VAF 41/369 reads (11%) | called by muse, mutect2, varscan2
- GXYLT2 | c.796G>T p.V266F | Missense Mutation (SNP) | VAF 32/234 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- HAT1 | c.445C>G p.L149V | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2
- HELZ2 | c.7507A>G p.I2503V (on ENST00000467148 / NM_001037335.2; = p.I1934V on NM_033405.3) | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- HHLA1 | c.1109del p.L370Wfs*7 | Frame Shift Del (DEL) | VAF 45/422 reads (11%) | called by mutect2, pindel, varscan2
- HHLA1 | c.109G>C p.E37Q | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); called by muse, mutect2
- HIC1 | c.814C>T p.P272S (on ENST00000322941 / NM_001098202.1; = p.P253S on NM_006497.4) | Missense Mutation (SNP) | VAF 59/448 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HNRNPD | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.074); called by muse, mutect2
- INF2 | c.1888-1G>A p.X630_splice | Splice Site (SNP) | VAF 10/264 reads (4%) | called by muse, mutect2
- INO80 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- IRX2 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.204); called by muse, mutect2
- ITGAE | c.712G>C p.E238Q | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- KIRREL1 | c.1792A>T p.M598L | Missense Mutation (SNP) | VAF 28/259 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLF10 | c.1224G>T p.R408S | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- KLF2 | c.734C>A p.P245Q | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- KLHL42 | c.1013C>G p.S338C | Missense Mutation (SNP) | VAF 21/260 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- KRTAP10-11 | c.439T>C p.C147R | Missense Mutation (SNP) | VAF 47/656 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.396); called by muse, mutect2
- KRTAP10-11 | c.440G>C p.C147S | Missense Mutation (SNP) | VAF 46/660 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.026); called by muse, mutect2
- LLGL2 | c.969G>C p.Q323H | Missense Mutation (SNP) | VAF 16/248 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2
- LRCH4 | c.1025A>T p.K342M | Missense Mutation (SNP) | VAF 31/201 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- LRP1B | c.2798C>T p.S933F | Missense Mutation (SNP) | VAF 12/167 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); called by muse, mutect2
- LZIC | c.493G>C p.E165Q | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MACF1 | c.14896A>G p.I4966V (on ENST00000372915; = p.I2899V on NM_012090.5) | Missense Mutation (SNP) | VAF 24/171 reads (14%) | called by muse, mutect2
- MALRD1 | c.5782G>A p.D1928N | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); called by muse, mutect2, varscan2
- MAST3 | c.1283T>C p.V428A | Missense Mutation (SNP) | VAF 51/497 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MICAL3 | c.2503C>T p.P835S | Missense Mutation (SNP) | VAF 28/304 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MMUT | c.2189A>G p.K730R | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.029); called by muse, mutect2
- MSRB2 | c.79G>T p.G27C | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- MSRB3 | c.513C>G p.F171L | Missense Mutation (SNP) | VAF 8/108 reads (7%) | PolyPhen benign (0.302); called by muse, mutect2
- MYH4 | c.3070C>A p.L1024M | Missense Mutation (SNP) | VAF 40/336 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MYO7A | c.2941G>T p.D981Y | Missense Mutation (SNP) | VAF 26/188 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); called by muse, mutect2
- NBPF12 | c.1762C>G p.Q588E | Missense Mutation (SNP) | VAF 34/383 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.34); called by muse, mutect2
- NBPF9 | c.1137G>T p.Q379H | Missense Mutation (SNP) | VAF 46/426 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- NKX2-6 | c.824G>A p.S275N | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NOP56 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 10/110 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2
- NOTCH1 | c.2816dup p.T940Hfs*4 | Frame Shift Ins (INS) | VAF 60/411 reads (15%) | called by mutect2, pindel, varscan2
- NR1H2 | c.872T>C p.F291S | Missense Mutation (SNP) | VAF 18/239 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR12D2 | c.569C>A p.T190N | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- OR2T6 | c.679C>G p.Q227E | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- OR4N5 | c.152C>G p.S51* | Nonsense Mutation (SNP) | VAF 26/137 reads (19%) | called by muse, mutect2, varscan2
- OTUD7A | c.2779G>A p.E927K (on ENST00000307050 / NM_001382637.1; = p.E920K on NM_130901.3) | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- OVCH1 | c.1317G>C p.L439F | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- PCDH11X | c.244G>T p.G82C | Missense Mutation (SNP) | VAF 52/219 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDH7 | c.2756dup p.H919Qfs*11 | Frame Shift Ins (INS) | VAF 31/287 reads (11%) | called by mutect2, pindel
- PCDHAC1 | c.632C>T p.P211L | Missense Mutation (SNP) | VAF 25/261 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCNT | c.2059G>C p.E687Q | Missense Mutation (SNP) | VAF 18/356 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); called by muse, mutect2
- PDE6A | c.845T>G p.M282R | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PEG3 | c.1350G>C p.M450I | Missense Mutation (SNP) | VAF 21/191 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- PIBF1 | c.1466A>G p.E489G | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- PLEKHA5 | c.3118G>C p.D1040H | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.336); called by muse, mutect2
- PLPPR3 | c.1596C>G p.N532K (on ENST00000520876 / NM_001270366.2; = p.N560K on NM_024888.2) | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- POMK | c.962G>C p.R321T | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PPP2CA | c.455A>G p.Y152C | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- PRAMEF10 | c.360G>T p.R120S | Missense Mutation (SNP) | VAF 13/184 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PRDM7 | c.72C>G p.V24= | Splice Region (SNP) | VAF 8/170 reads (5%) | called by muse, mutect2
- PSMD1 | c.2198C>A p.A733D | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- PUM3 | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, varscan2
- PYROXD1 | c.906G>C p.L302F | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RAB6D | c.371T>C p.V124A | Missense Mutation (SNP) | VAF 30/264 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- RABGAP1 | c.2501C>G p.P834R | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- RALGAPB | c.888G>C p.L296F | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RBPJ | c.1245G>T p.W415C | Missense Mutation (SNP) | VAF 30/193 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- REXO4 | c.370G>C p.D124H | Missense Mutation (SNP) | VAF 14/390 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.168); called by muse, mutect2
- RIC1 | c.2803G>A p.D935N | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.829); called by muse, mutect2
- RPL26 | c.421G>C p.E141Q | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2
- RPTN | c.1007G>C p.R336T | Missense Mutation (SNP) | VAF 38/454 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); called by muse, mutect2
- RUNDC3A | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 11/229 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.069); called by muse, mutect2
- SAMD9 | c.1460A>T p.H487L | Missense Mutation (SNP) | VAF 22/292 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2
- SH3TC2 | c.2320G>A p.D774N | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.149); called by muse, mutect2
- SHANK3 | c.3511G>A p.E1171K | Missense Mutation (SNP) | VAF 36/486 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); called by muse, mutect2
- SIVA1 | c.313+3G>A | Splice Region (SNP) | VAF 24/431 reads (6%) | called by muse, mutect2
- SLA | c.482C>G p.S161C (on ENST00000338087 / NM_001045556.3; = p.S201C on NM_006748.4) | Missense Mutation (SNP) | VAF 6/128 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.055); called by muse, mutect2
- SLC25A6 | c.343G>T p.G115C | Missense Mutation (SNP) | VAF 59/663 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SLC4A2 | c.515C>G p.S172C | Missense Mutation (SNP) | VAF 31/349 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.088); called by muse, mutect2
- SLC9C1 | c.1600G>A p.E534K | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.475); called by muse, mutect2
- SNW1 | c.406G>T p.D136Y | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- SOCS4 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SPATA31D1 | c.526C>A p.P176T | Missense Mutation (SNP) | VAF 47/334 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SRCIN1 | c.2170G>A p.E724K (on ENST00000621492; = p.E690K on NM_025248.3) | Missense Mutation (SNP) | VAF 24/402 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- SUPV3L1 | c.466G>C p.D156H | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- SYNE2 | c.4422T>A p.D1474E | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TAFA5 | c.110G>T p.C37F | Missense Mutation (SNP) | VAF 31/204 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- TECPR1 | c.629C>T p.S210L | Missense Mutation (SNP) | VAF 41/195 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- TEX11 | c.2062G>A p.V688I (on ENST00000344304; = p.V673I on NM_031276.3) | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- TGFBRAP1 | c.1111G>C p.E371Q | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.459); called by muse, mutect2
- TLR7 | c.2904G>C p.K968N | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- TMEM108 | c.1147C>G p.P383A | Missense Mutation (SNP) | VAF 31/280 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); called by muse, mutect2
- TMEM235 | c.248C>G p.S83C | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); called by muse, mutect2
- TMEM240 | c.384G>A p.W128* | Nonsense Mutation (SNP) | VAF 11/157 reads (7%) | called by muse, mutect2
- TMEM87A | c.1627G>T p.E543* | Nonsense Mutation (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- TSSC4 | c.535C>T p.Q179* | Nonsense Mutation (SNP) | VAF 15/137 reads (11%) | called by muse, mutect2, varscan2
- TTN | c.9636G>T p.Q3212H (on ENST00000591111; = p.Q3166H on NM_003319.4) | Missense Mutation (SNP) | VAF 21/201 reads (10%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- TXNRD2 | c.928G>A p.D310N | Missense Mutation (SNP) | VAF 36/488 reads (7%) | SIFT tolerated (0.69); PolyPhen benign (0.136); called by muse, mutect2
- USF3 | c.5801A>T p.H1934L | Missense Mutation (SNP) | VAF 9/177 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- USP53 | c.506G>A p.G169E | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- VPS13D | c.11449A>G p.K3817E | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- WDFY3 | c.2245G>A p.E749K | Missense Mutation (SNP) | VAF 16/173 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.009); called by muse, mutect2
- WSCD2 | c.518T>A p.L173Q | Missense Mutation (SNP) | VAF 61/459 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- XPO4 | c.3087G>T p.L1029F | Missense Mutation (SNP) | VAF 11/165 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); called by muse, mutect2
- ZBTB49 | c.1447A>T p.I483F | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); called by muse, mutect2
- ZC3H7B | c.2735G>C p.G912A | Missense Mutation (SNP) | VAF 29/341 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2
- ZCCHC4 | c.1480C>G p.H494D | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.015); called by muse, mutect2
- ZIC1 | c.215C>A p.A72E | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- ZNF121 | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.046); called by muse, mutect2
- ZNF250 | c.524G>T p.R175L | Missense Mutation (SNP) | VAF 26/302 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2
- ZNF324B | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 39/383 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- ZNF436 | c.1001A>T p.Y334F | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.134); called by muse, mutect2
- ZNF844 | c.970C>T p.L324F | Missense Mutation (SNP) | VAF 21/230 reads (9%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.673); called by muse, mutect2
- ABCA13 | c.4902G>A p.L1634= | Silent (SNP) | VAF 15/234 reads (6%) | called by muse, mutect2
- ABHD16B | c.945G>A p.L315= | Silent (SNP) | VAF 21/269 reads (8%) | catalogued as rs1226751446; called by muse, mutect2
- AC109583.1 | c.156C>T p.P52= | Silent (SNP) | VAF 53/528 reads (10%) | catalogued as rs1385205670; called by muse, mutect2, varscan2
- ADAM19 | c.2433G>C p.L811= | Silent (SNP) | VAF 19/284 reads (7%) | called by muse, mutect2
- ADAMTS9 | c.192C>A p.P64= | Silent (SNP) | VAF 42/274 reads (15%) | called by muse, mutect2, varscan2
- ADCK5 | c.1191C>G p.L397= | Silent (SNP) | VAF 12/78 reads (15%) | called by muse, mutect2, varscan2
- ADGRB1 | c.3141C>A p.R1047= | Silent (SNP) | VAF 28/262 reads (11%) | called by muse, mutect2, varscan2
- ADGRD2 | c.1677C>T p.F559= | Silent (SNP) | VAF 24/244 reads (10%) | catalogued as rs754062201; called by muse, mutect2, varscan2
- ALPL | c.282C>T p.F94= | Silent (SNP) | VAF 26/357 reads (7%) | catalogued as rs746608270; called by muse, mutect2
- ARID1A | c.3063G>A p.K1021= | Silent (SNP) | VAF 10/204 reads (5%) | catalogued as COSV100250494; called by muse, mutect2
- ASB10 | c.408G>C p.L136= (on ENST00000420175 / NM_001142459.2; = p.L121= on NM_080871.4) | Silent (SNP) | VAF 21/468 reads (4%) | called by muse, mutect2
- ATP2B2 | c.1089G>A p.K363= (on ENST00000352432; = p.K329= on NM_001683.5) | Silent (SNP) | VAF 13/263 reads (5%) | called by muse, mutect2
- BIRC6 | c.1737T>C p.A579= | Silent (SNP) | VAF 16/130 reads (12%) | called by muse, mutect2, varscan2
- BRCA1 | c.4896G>C p.V1632= | Silent (SNP) | VAF 14/158 reads (9%) | called by muse, mutect2
- C5orf63 | c.6C>T p.L2= | Silent (SNP) | VAF 13/167 reads (8%) | called by muse, mutect2
- CALCRL | c.717A>T p.T239= | Silent (SNP) | VAF 15/170 reads (9%) | catalogued as COSV66477463; called by muse, mutect2
- CBX7 | c.18C>T p.I6= | Silent (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2
- CDIPT | c.573C>T p.V191= | Silent (SNP) | VAF 11/152 reads (7%) | catalogued as rs1162385532; called by muse, mutect2
- CDX1 | c.339G>T p.A113= | Silent (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- COL22A1 | c.2433C>T p.F811= | Silent (SNP) | VAF 21/249 reads (8%) | catalogued as rs767824998; called by muse, mutect2
- COMT | c.774G>A p.E258= | Silent (SNP) | VAF 22/366 reads (6%) | catalogued as rs1274476196; called by muse, mutect2
- CSMD3 | c.1476A>T p.P492= (on ENST00000297405 / NM_001363185.1; = p.P388= on NM_052900.3) | Silent (SNP) | VAF 18/183 reads (10%) | called by muse, mutect2
- CYP27C1 | c.453G>C p.V151= | Silent (SNP) | VAF 16/266 reads (6%) | catalogued as rs927313893; called by muse, mutect2
- DLG1 | c.1257C>T p.I419= | Silent (SNP) | VAF 5/49 reads (10%) | called by muse, mutect2, varscan2
- EFR3B | c.2154C>A p.A718= | Silent (SNP) | VAF 33/301 reads (11%) | called by muse, mutect2, varscan2
- ENPP1 | c.2010C>T p.T670= | Silent (SNP) | VAF 11/122 reads (9%) | catalogued as rs762920235; called by muse, mutect2
- EPN2 | c.192G>A p.L64= | Silent (SNP) | VAF 13/130 reads (10%) | catalogued as COSV59063665; called by muse, mutect2, varscan2
- FNIP1 | c.1437A>G p.K479= | Silent (SNP) | VAF 11/92 reads (12%) | catalogued as COSV100330149; called by muse, mutect2, varscan2
- FUT7 | c.57C>A p.A19= | Silent (SNP) | VAF 53/496 reads (11%) | called by muse, mutect2, varscan2
- GPR26 | c.120G>A p.A40= | Silent (SNP) | VAF 25/253 reads (10%) | called by muse, mutect2, varscan2
- GPSM3 | c.258C>A p.T86= | Silent (SNP) | VAF 25/208 reads (12%) | called by mutect2, varscan2
- GRID1 | c.2940G>A p.P980= | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as rs372199655, COSV60038726; called by muse, mutect2, varscan2
- GTF2IRD1 | c.432G>C p.L144= | Silent (SNP) | VAF 7/63 reads (11%) | called by muse, mutect2
- H4C4 | c.177G>A p.L59= | Silent (SNP) | VAF 22/326 reads (7%) | catalogued as COSV61591681; called by muse, mutect2
- HOXD12 | c.216C>T p.F72= | Silent (SNP) | VAF 22/241 reads (9%) | called by muse, mutect2
- IGF1 | c.336C>G p.L112= | Silent (SNP) | VAF 19/240 reads (8%) | catalogued as COSV100190359; called by muse, mutect2
- ITGAV | c.153C>T p.F51= | Silent (SNP) | VAF 16/208 reads (8%) | catalogued as rs1157905919, COSV53710618; called by muse, mutect2
- KY | c.1005G>A p.Q335= | Silent (SNP) | VAF 15/255 reads (6%) | catalogued as rs1177358565; called by muse, mutect2
- LAMB3 | c.2005C>T p.L669= | Silent (SNP) | VAF 20/186 reads (11%) | called by muse, mutect2
- LENG8 | c.2581C>T p.L861= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as rs1006042438; called by muse, mutect2, varscan2
- MAST1 | c.687G>A p.R229= | Silent (SNP) | VAF 57/528 reads (11%) | catalogued as COSV99262313; called by muse, mutect2, varscan2
- MELTF | c.72G>C p.R24= | Silent (SNP) | VAF 19/172 reads (11%) | called by muse, mutect2, varscan2
- MFSD8 | c.39C>G p.L13= | Silent (SNP) | VAF 24/514 reads (5%) | catalogued as COSV56553321; called by muse, mutect2
- MICAL3 | c.3963C>T p.S1321= | Silent (SNP) | VAF 28/206 reads (14%) | catalogued as rs986448287, COSV101490978; called by muse, mutect2, varscan2
- MLNR | c.1131G>A p.P377= | Silent (SNP) | VAF 29/427 reads (7%) | catalogued as COSV54534072; called by muse, mutect2
- MUC6 | c.1704G>A p.P568= | Silent (SNP) | VAF 35/211 reads (17%) | catalogued as rs756257302; called by muse, mutect2, varscan2
- MYCBP2 | c.9177G>A p.L3059= (on ENST00000357337; = p.L3097= on NM_015057.5) | Silent (SNP) | VAF 6/56 reads (11%) | called by muse, mutect2, varscan2
- MYO3B | c.2592G>C p.L864= | Silent (SNP) | VAF 15/268 reads (6%) | catalogued as COSV58695161; called by muse, mutect2
- MYOF | c.3414C>T p.I1138= | Silent (SNP) | VAF 6/94 reads (6%) | called by muse, mutect2
- NLRP11 | c.2226C>G p.L742= | Silent (SNP) | VAF 11/157 reads (7%) | called by muse, mutect2
- NQO1 | c.472C>T p.L158= | Silent (SNP) | VAF 13/281 reads (5%) | catalogued as COSV57732593; called by muse, mutect2
- NRXN2 | c.978G>C p.L326= | Silent (SNP) | VAF 38/620 reads (6%) | called by muse, mutect2
- OR8J3 | c.549T>G p.P183= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV56882052; called by muse, mutect2, varscan2
- OTOGL | c.5730G>T p.T1910= (on ENST00000547103; = p.T1901= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 17/194 reads (9%) | catalogued as rs762557747, COSV100087576, COSV54020253; called by muse, mutect2
- PDRG1 | c.159C>T p.L53= | Silent (SNP) | VAF 7/156 reads (4%) | catalogued as rs1325672736; called by muse, mutect2
- PIK3AP1 | c.1137T>A p.A379= | Silent (SNP) | VAF 20/284 reads (7%) | called by muse, mutect2
- PLEKHA8 | c.1461G>A p.Q487= | Silent (SNP) | VAF 32/349 reads (9%) | catalogued as COSV51649738; called by muse, mutect2
- PRUNE2 | c.6201G>A p.A2067= | Silent (SNP) | VAF 25/145 reads (17%) | catalogued as rs766091567, COSV65047157; called by muse, mutect2, varscan2
- RAD23A | c.1068G>A p.L356= | Silent (SNP) | VAF 28/236 reads (12%) | catalogued as rs1338497991; called by muse, mutect2, varscan2
- RAI1 | c.1899C>T p.V633= | Silent (SNP) | VAF 30/407 reads (7%) | catalogued as COSV99883524; called by muse, mutect2
- RCN1 | c.129G>A p.S43= | Silent (SNP) | VAF 56/490 reads (11%) | called by muse, mutect2, varscan2
- RHBDF2 | c.621C>T p.A207= | Silent (SNP) | VAF 7/45 reads (16%) | called by muse, mutect2, varscan2
- RNF4 | c.540C>T p.I180= | Silent (SNP) | VAF 22/268 reads (8%) | catalogued as COSV58642631; called by muse, mutect2
- RYR2 | c.12729G>A p.S4243= | Silent (SNP) | VAF 40/444 reads (9%) | catalogued as rs1409008799, COSV63680125, COSV63701252; called by muse, mutect2
- SASS6 | c.417A>G p.L139= | Silent (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- SEC14L6 | c.552G>A p.E184= | Silent (SNP) | VAF 14/128 reads (11%) | called by muse, mutect2
- SENP6 | c.732G>A p.L244= | Silent (SNP) | VAF 16/248 reads (6%) | called by muse, mutect2
- SIM1 | c.1335C>G p.L445= | Silent (SNP) | VAF 15/143 reads (10%) | called by muse, mutect2, varscan2
- SLC12A9 | c.2238C>A p.L746= | Silent (SNP) | VAF 22/408 reads (5%) | catalogued as COSV51937277; called by muse, mutect2
- SLC4A10 | c.2205C>T p.S735= (on ENST00000446997 / NM_001354461.2; = p.S705= on NM_022058.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 13/165 reads (8%) | called by muse, mutect2
- SOGA1 | c.579C>G p.L193= | Silent (SNP) | VAF 9/232 reads (4%) | called by muse, mutect2
- SORCS1 | c.99C>A p.G33= | Silent (SNP) | VAF 4/37 reads (11%) | called by muse, mutect2, varscan2
- SOX7 | c.1089G>A p.T363= | Silent (SNP) | VAF 48/588 reads (8%) | catalogued as rs375704044, COSV100449137; called by muse, mutect2
- SYBU | c.1524G>A p.Q508= (on ENST00000276646 / NM_001099754.2; = p.Q507= on NM_017786.6) | Silent (SNP) | VAF 20/254 reads (8%) | catalogued as COSV52618114; called by muse, mutect2
- SYCE1 | c.687C>G p.L229= (on ENST00000343131 / NM_001143764.3; = p.L193= on NM_130784.3) | Silent (SNP) | VAF 10/124 reads (8%) | called by muse, mutect2
- TAS2R5 | c.297C>T p.L99= | Silent (SNP) | VAF 13/234 reads (6%) | called by muse, mutect2
- TBX15 | c.1647C>T p.N549= (on ENST00000369429 / NM_001330677.2; = p.N443= on NM_152380.3) | Silent (SNP) | VAF 22/251 reads (9%) | catalogued as COSV52874650, COSV99253681; called by muse, mutect2
- TCHH | c.2409C>T p.R803= | Silent (SNP) | VAF 23/369 reads (6%) | called by muse, mutect2
- TICAM1 | c.127C>T p.L43= | Silent (SNP) | VAF 28/221 reads (13%) | called by muse, mutect2, varscan2
- TM4SF19 | c.339C>T p.V113= | Silent (SNP) | VAF 13/198 reads (7%) | catalogued as COSV99879286; called by muse, mutect2
- UBQLN1 | c.909A>G p.T303= | Silent (SNP) | VAF 21/145 reads (14%) | catalogued as rs762879940; called by muse, mutect2, varscan2
- UGDH | c.537G>A p.L179= | Silent (SNP) | VAF 28/252 reads (11%) | catalogued as rs1341915083; called by muse, varscan2
- WASHC2A | c.978G>A p.K326= | Silent (SNP) | VAF 14/288 reads (5%) | called by muse, mutect2
- YY2 | c.825C>T p.L275= | Silent (SNP) | VAF 14/72 reads (19%) | called by muse, mutect2, varscan2
- ZBP1 | c.633G>A p.G211= | Silent (SNP) | VAF 24/342 reads (7%) | called by muse, mutect2
- ZFHX3 | c.3309C>T p.L1103= | Silent (SNP) | VAF 18/372 reads (5%) | called by muse, mutect2
- ZIC4 | c.480G>T p.V160= | Silent (SNP) | VAF 120/672 reads (18%) | called by muse, mutect2, varscan2
- ZNF454 | c.1071A>G p.E357= | Silent (SNP) | VAF 12/143 reads (8%) | called by muse, mutect2
- ZNF469 | c.8580G>T p.P2860= (on ENST00000437464; = p.P2888= on NM_001367624.2) | Silent (SNP) | VAF 43/409 reads (11%) | called by muse, mutect2, varscan2
- ZNF567 | c.1002G>A p.E334= (on ENST00000536254 / NM_001322913.1; = p.E303= on NM_152603.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 17/250 reads (7%) | called by muse, mutect2
- AC092865.4 | n.179G>A | RNA (SNP) | VAF 58/470 reads (12%) | called by muse, mutect2, varscan2
- ALMS1P1 | n.1001C>A | RNA (SNP) | VAF 19/246 reads (8%) | catalogued as rs765313362; called by muse, mutect2
- APTX | c.874+40C>G | Intron (SNP) | VAF 11/96 reads (11%) | called by muse, mutect2, varscan2
- ARHGAP27 | c.657+76G>C | Intron (SNP) | VAF 22/205 reads (11%) | called by muse, mutect2, varscan2
- ARHGEF25 | chr12:57620300 C>T | 3'Flank (SNP) | VAF 22/169 reads (13%) | called by muse, mutect2, varscan2
- BFSP2 | c.*42C>G | 3'UTR (SNP) | VAF 22/232 reads (9%) | catalogued as COSV100183765; called by muse, mutect2
- C3 | c.4172+18C>T | Intron (SNP) | VAF 35/244 reads (14%) | catalogued as rs759470368; called by muse, mutect2, varscan2
- CACNA2D1 | c.1362+23C>G | Intron (SNP) | VAF 14/191 reads (7%) | called by muse, mutect2
- CCDC65 | chr12:48923902 C>T | 3'Flank (SNP) | VAF 24/337 reads (7%) | catalogued as rs201919405; called by muse, mutect2
- CCM2 | chr7:44999815 C>T | 5'Flank (SNP) | VAF 7/76 reads (9%) | called by muse, mutect2
- CRACR2B | c.953+64C>G | Intron (SNP) | VAF 20/177 reads (11%) | catalogued as rs749831190; called by muse, mutect2, varscan2
- CTNND1 | c.2809-35C>G | Intron (SNP) | VAF 8/60 reads (13%) | catalogued as COSV100649742; called by muse, mutect2
- DEPDC5 | c.3030+3812C>A | Intron (SNP) | VAF 19/164 reads (12%) | catalogued as CS160830; called by muse, varscan2
- EFCAB2 | c.*24C>A | 3'UTR (SNP) | VAF 6/32 reads (19%) | called by muse, mutect2, varscan2
- EPSTI1 | chr13:42888312 C>T | 3'Flank (SNP) | VAF 17/219 reads (8%) | called by muse, mutect2
- GDAP1 | c.*1060C>T | 3'UTR (SNP) | VAF 9/95 reads (9%) | called by muse, varscan2
- HLTF | c.-32G>T | 5'UTR (SNP) | VAF 20/216 reads (9%) | called by muse, mutect2
- IMPA1 | c.-25+347G>T | Intron (SNP) | VAF 14/174 reads (8%) | catalogued as rs1419815630; called by muse, mutect2
- KCNK9 | chr8:139703020 G>C | 5'Flank (SNP) | VAF 29/240 reads (12%) | called by muse, mutect2, varscan2
- LINC00602 | n.905C>A | RNA (SNP) | VAF 13/90 reads (14%) | called by muse, mutect2, varscan2
- MASP1 | c.1303+5134G>C | Intron (SNP) | VAF 34/483 reads (7%) | catalogued as COSV56220639; called by muse, mutect2
- MOV10L1 | c.97+314C>A | Intron (SNP) | VAF 30/384 reads (8%) | catalogued as COSV99435123; called by muse, mutect2
- MRPS10 | c.*37G>C | 3'UTR (SNP) | VAF 10/197 reads (5%) | called by muse, mutect2
- MRPS22 | c.173-14G>C | Intron (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2, varscan2
- NDUFS4 | c.*41C>T | 3'UTR (SNP) | VAF 16/114 reads (14%) | called by muse, mutect2, varscan2
- NET1 | c.-9C>T | 5'UTR (SNP) | VAF 20/237 reads (8%) | called by muse, mutect2
- NPY6R | n.639G>C | RNA (SNP) | VAF 9/92 reads (10%) | called by muse, mutect2, varscan2
- NTNG2 | c.1054+867_1054+880del | Intron (DEL) | VAF 8/44 reads (18%) | called by mutect2, pindel
- OBSCN | c.18661+3199G>T | Intron (SNP) | VAF 50/446 reads (11%) | called by muse, mutect2, varscan2
- PDHB | c.934+49T>C | Intron (SNP) | VAF 15/150 reads (10%) | called by muse, mutect2
- PPP4R1L | n.488G>C | RNA (SNP) | VAF 14/114 reads (12%) | called by muse, mutect2, varscan2
- PXMP2 | c.*45G>C | 3'UTR (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2
- RPS17 | c.*274C>G | 3'UTR (SNP) | VAF 38/506 reads (8%) | called by muse, mutect2
- RPS17 | c.262-13C>G | Intron (SNP) | VAF 29/442 reads (7%) | called by muse, mutect2
- SAFB | c.2552-30T>G | Intron (SNP) | VAF 25/168 reads (15%) | called by muse, mutect2, varscan2
- SIPA1L1 | c.-302-13971G>A | Intron (SNP) | VAF 10/266 reads (4%) | called by muse, mutect2
- SORBS2 | c.-197-6015G>C | Intron (SNP) | VAF 21/240 reads (9%) | catalogued as rs1490561221; called by muse, mutect2
- TERT | c.-45G>T | 5'UTR (SNP) | VAF 11/61 reads (18%) | catalogued as COSV57209080; called by muse, mutect2
- TMEM254 | c.88-170A>T | Intron (SNP) | VAF 10/91 reads (11%) | called by muse, mutect2, varscan2
- VEPH1 | c.138+1940C>T | Intron (SNP) | VAF 12/139 reads (9%) | catalogued as rs377725120; called by muse, mutect2
- ZFAND1 | c.55+16C>G | Intron (SNP) | VAF 20/362 reads (6%) | called by muse, mutect2
- ZNF829 | c.-56C>G | 5'UTR (SNP) | VAF 10/94 reads (11%) | called by muse, mutect2, varscan2
